Somatic mutation profile of tumor specimen TCGA-DJ-A13M-01A (aliquot TCGA-DJ-A13M-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.8 years (10,530 days).
Specimen TCGA-DJ-A13M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be8700a0-0312-4344-9ea2-25acaa9f8d58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13M-10A (Blood Derived Normal), aliquot TCGA-DJ-A13M-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea10eec6-4839-4082-bd53-3a1ab2404071

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 64/149 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC5A2 | c.1081T>G p.C361G | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368508156, COSV57893180; called by muse, mutect2, varscan2
- TBX20 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs747369702, CM086967, COSV68784745; called by muse, mutect2, varscan2
- WDR62 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV54337477; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505834 C>G | 5'Flank (SNP) | VAF 56/112 reads (50%) | catalogued as rs760389502; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85675C>T | Intron (SNP) | VAF 71/196 reads (36%) | catalogued as COSV72275493; called by muse, mutect2, varscan2
